Somatic mutation profile of tumor specimen C3L-02648-02 (aliquot CPT0204600010) from CPTAC case C3L-02648, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 72.9 years (26,627 days).
Specimen C3L-02648-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a8827a6-0df0-4a1b-abc0-c4c42f0786a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02648-31 (Blood Derived Normal), aliquot CPT0204750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d413788f-a54d-49cb-85d2-f5b62b6315f1

The open-access MAF lists 337 somatic variants for this specimen: 231 protein-altering or splice-affecting, 77 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 77, Nonsense Mutation 18, Intron 14, 3'UTR 7, Frame Shift Del 7, RNA 4, Splice Site 3, 5'UTR 2, Frame Shift Ins 2, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs886037990, COSV100524285, COSV58784706, COSV58788589; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 13/401 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs867882536, CM122522; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.761T>A p.I254N | Missense Mutation (SNP) | VAF 63/263 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151471, COSV52674699, COSV52714188, COSV52767322; called by muse, mutect2, varscan2
- ACVR2B | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 105/501 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV61702435; called by muse, mutect2, varscan2
- ADAM2 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs907635766, COSV55863839; called by muse, mutect2, varscan2
- ADAMTS14 | c.2032A>T p.S678C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1006434722; called by muse, mutect2, varscan2
- ADGRB3 | c.4085A>T p.N1362I | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV53239703; called by muse, mutect2, varscan2
- ANXA11 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs140133265, COSV99627232; called by muse, mutect2, varscan2
- C19orf81 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70766501; called by muse, mutect2, varscan2
- CACHD1 | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs556698065, COSV99263546; called by muse, mutect2, varscan2
- CACNA1H | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs185769412, COSV61983363; called by muse, mutect2
- CBLB | c.1304G>A p.C435Y | Missense Mutation (SNP) | VAF 91/453 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); catalogued as rs116474782; ClinVar: not provided; called by muse, mutect2, varscan2
- CD209 | c.1088G>C p.G363A | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765147780; called by muse, mutect2, varscan2
- CHP2 | c.475C>A p.R159S | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55649193; called by muse, mutect2, varscan2
- CLEC14A | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV60561739; called by muse, mutect2
- COG8 | c.1072C>G p.R358G | Missense Mutation (SNP) | VAF 97/632 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54742714; called by muse, mutect2, varscan2
- COL19A1 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs542225284, COSV59568832; called by muse, mutect2, varscan2
- CYP2C9 | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV53247741; called by muse, mutect2, varscan2
- CYP4X1 | c.659G>C p.S220T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.062); catalogued as COSV64150132; called by muse, mutect2, varscan2
- DNAH17 | c.5975A>C p.E1992A | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV101101662; called by muse, mutect2, varscan2
- DNAH5 | c.9106G>A p.V3036I | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.13); catalogued as rs1160342036, COSV54217596; called by muse, mutect2, varscan2
- DOCK8 | c.5207C>T p.A1736V | Missense Mutation (SNP) | VAF 62/359 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs139990627; called by muse, mutect2, varscan2
- DSG1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57133385; called by muse, mutect2, varscan2
- DYNC2H1 | c.11776A>G p.I3926V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs1454901287; called by muse, mutect2, varscan2
- EP400 | c.3409G>T p.G1137C | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202319; called by muse, mutect2, varscan2
- ERBB4 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as COSV53566690, COSV53591179; called by muse, mutect2, varscan2
- FGA | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 91/454 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120213; called by muse, mutect2, varscan2
- FHOD1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs762232923; called by muse, varscan2
- FNDC1 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs765391579; called by muse, mutect2
- GP5 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99756538; called by muse, mutect2, varscan2
- GPRC6A | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as rs781062631; called by muse, mutect2, varscan2
- KCNA1 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230345; called by muse, mutect2, varscan2
- KNDC1 | c.519del p.L174Cfs*94 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as COSV100464862; called by mutect2, varscan2*
- KRTAP5-1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 51/276 reads (18%) | PolyPhen benign (0.134); catalogued as rs1179553681; called by muse, mutect2, varscan2
- LRRC63 | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV101115796; called by muse, mutect2, varscan2
- MCPH1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs1390169606; called by muse, mutect2, varscan2
- MDGA2 | c.2653C>A p.L885I (on ENST00000399232 / NM_001113498.2; = p.L587I on NM_182830.4) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV62080632; called by muse, mutect2
- MKRN3 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs775128922, COSV100090889, COSV100091610; called by muse, mutect2, varscan2
- MSANTD4 | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs1396922431; called by muse, mutect2, varscan2
- MYH11 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 31/344 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1432299511; called by muse, mutect2
- MYLK | c.5027C>G p.A1676G | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100659629; called by muse, mutect2, varscan2
- NAV3 | c.2111G>C p.R704P | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57112344; called by muse, mutect2, varscan2
- NF2 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV58527485; called by muse, mutect2, varscan2
- NPAP1 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV61506256; called by muse, mutect2, varscan2
- NSMAF | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs765849706; called by muse, mutect2, varscan2
- NUMBL | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs1164547461; called by muse, mutect2, varscan2
- OLFM3 | c.1234A>G p.T412A (on ENST00000338858 / NM_001288821.1; = p.T392A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58799935; called by muse, mutect2
- OR14C36 | c.354T>A p.H118Q | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58601226; called by muse, mutect2, varscan2
- OR2M5 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63545760; called by muse, mutect2, varscan2
- OR2T6 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.277); catalogued as COSV100861574; called by muse, mutect2, varscan2
- OR5H6 | c.662C>T p.S221F (on ENST00000642105; = p.S205F on NM_001005479.2) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.93); catalogued as COSV67351545; called by muse, mutect2
- OR5T2 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV57587806; called by muse, mutect2
- OR6C4 | c.406A>G p.S136G | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV67793057; called by muse, mutect2, varscan2
- PAG1 | c.457G>C p.G153R | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV55060679; called by muse, mutect2, varscan2
- PCDHGA1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65294812, COSV65300168; called by muse, mutect2, varscan2
- PCDHGB3 | c.2228A>G p.Y743C | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs1231771489; called by muse, mutect2, varscan2
- PKHD1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.941); catalogued as COSV100585024; called by muse, mutect2, varscan2
- POTEJ | c.1901T>A p.L634Q | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as rs1473057215; called by muse, mutect2
- POU3F1 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as rs766228279; called by muse, mutect2
- PTPRG | c.1719C>A p.D573E | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as COSV55635162; called by muse, mutect2, varscan2
- PXDN | c.2530G>T p.G844* | Nonsense Mutation (SNP) | VAF 58/293 reads (20%) | catalogued as COSV53228001, COSV99413418; called by muse, mutect2, varscan2
- R3HDML | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407152; called by muse, mutect2, varscan2
- RAD51AP1 | c.559G>A p.G187S (on ENST00000228843 / NM_001130862.2; = p.G170S on NM_006479.5) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as COSV57411084; called by muse, mutect2, varscan2
- RALYL | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1166308465; called by muse, varscan2
- RFX6 | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as rs1218313498, COSV60588163; called by muse, mutect2, varscan2
- RNF113B | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564848599; called by muse, mutect2, varscan2
- RTN4R | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 161/478 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs144550064; called by muse, mutect2, varscan2
- SBK2 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs990574585; called by muse, mutect2
- SCN1A | c.2657C>A p.S886Y (on ENST00000303395 / NM_001202435.3; = p.S875Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57664511; called by muse, mutect2, varscan2
- SLC22A25 | c.1453del p.L485Sfs*2 | Frame Shift Del (DEL) | VAF 21/134 reads (16%) | catalogued as COSV100123442; called by mutect2, pindel, varscan2
- SLC39A12 | c.2028G>T p.W676C (on ENST00000377369 / NM_001145195.2; = p.W639C on NM_152725.3) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101070184, COSV104426486; called by muse, mutect2, varscan2
- SPAG6 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as COSV100509855; called by muse, mutect2, varscan2
- SPANXC | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as rs782568948; called by muse, mutect2
- SPTB | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760837664, COSV67632701, COSV67633172; called by muse, mutect2, varscan2
- STRA6 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 60/612 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as rs772927415; called by muse, mutect2
- TAAR9 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV71512174; called by muse, mutect2, varscan2
- TBX10 | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 92/434 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56875887; called by muse, mutect2, varscan2
- TEX13C | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs747025161; called by muse, mutect2, varscan2
- THSD1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99319034; called by muse, mutect2, varscan2
- TMTC1 | c.1156G>T p.G386C (on ENST00000539277 / NM_001193451.2; = p.G278C on NM_175861.3) | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55477210; called by muse, mutect2, varscan2
- TRPM3 | c.413C>T p.T138M (on ENST00000357533 / NM_001366142.2; = p.T107M on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1048349946, COSV100625118; called by muse, mutect2, varscan2
- TSKU | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV60750786; called by muse, mutect2, varscan2
- UGT1A1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.067); catalogued as rs780354743, COSV59385845; called by muse, mutect2, varscan2
- UGT2B28 | c.1476T>A p.D492E | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs559568989; called by muse, mutect2
- UNC13C | c.4055G>C p.G1352A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1270228757; called by muse, mutect2, varscan2
- ZNF222 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as rs368459134; called by muse, mutect2, varscan2
- ZNF37A | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.309); catalogued as COSV61072937, COSV61073686; called by muse, mutect2
- ZNF761 | c.1785A>G p.I595M | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as rs772105663; called by muse, mutect2, varscan2
- ACTR2 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAMTS12 | c.4253G>T p.S1418I | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ADAMTS20 | c.4263del p.W1421Cfs*32 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- ADSS1 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- AFAP1L2 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.07); called by muse, mutect2
- AKR7A2 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALB | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANGPTL4 | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 119/534 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AOC2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- APLNR | c.906C>A p.S302R | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP22 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2
- ARHGEF11 | c.4288G>C p.E1430Q | Missense Mutation (SNP) | VAF 9/268 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ARMC3 | c.1921A>T p.K641* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- ARMCX1 | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATXN1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPTF | c.7567G>A p.V2523I | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C10orf71 | c.2616G>T p.M872I | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C4orf54 | c.1817C>A p.S606Y | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- CABCOCO1 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2
- CACNA1G | c.5563G>T p.E1855* | Nonsense Mutation (SNP) | VAF 43/274 reads (16%) | called by muse, mutect2, varscan2
- CCDC85A | c.109T>A p.S37T | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CD209 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELA2A | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- CEP128 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- CIT | c.1887+6C>G | Splice Region (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- CNGA2 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 47/132 reads (36%) | called by muse, mutect2, varscan2
- COL14A1 | c.4726A>T p.T1576S | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL22A1 | c.2355+1G>T p.X785_splice | Splice Site (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- COL3A1 | c.2716G>C p.G906R | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CR2 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CRACD | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD2 | c.3821C>G p.T1274R | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DMD | c.7909G>C p.V2637L | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DMRTB1 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- DNAH6 | c.5227A>T p.M1743L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNM1L | c.771T>A p.S257R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DOCK4 | c.4963A>G p.S1655G | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPEP1 | c.508T>A p.C170S | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- DPY19L1 | c.1240G>T p.V414F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- EMC7 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- EPPK1 | c.4997C>A p.A1666D | Missense Mutation (SNP) | VAF 96/564 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH3 | c.2254G>C p.A752P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- EXOC3L1 | c.1222C>A p.H408N | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM161A | c.1328C>G p.S443* | Nonsense Mutation (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- FAM184B | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 18/555 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- FCGBP | c.7177C>T p.L2393F | Missense Mutation (SNP) | VAF 116/1087 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.223); called by muse, varscan2
- FERMT1 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 35/456 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- FHAD1 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FNDC1 | c.1586A>T p.K529M | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- FOXC2 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 80/701 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GDF10 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HIVEP2 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 66/378 reads (17%) | called by muse, mutect2, varscan2
- HYOU1 | c.1055G>T p.C352F | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-16 | c.10A>T p.R4* | Nonsense Mutation (SNP) | VAF 62/320 reads (19%) | called by muse, varscan2
- IGKV1D-17 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 63/653 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGLV2-33 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INPP5F | c.868G>T p.G290* | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | called by muse, varscan2
- IPP | c.1609G>T p.V537F | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IQGAP2 | c.108dup p.A37Cfs*3 | Frame Shift Ins (INS) | VAF 27/155 reads (17%) | called by mutect2, pindel, varscan2
- IWS1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- IWS1 | c.876G>T p.E292D | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNQ2 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2
- KCTD8 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KHDRBS3 | c.867C>G p.N289K | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); called by muse, mutect2
- KLHL1 | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNDC1 | c.516_517insT p.A173Cfs*4 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, varscan2*
- LHX5 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB6 | c.589A>T p.K197* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- MAP2 | c.2602G>T p.G868C | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MME | c.1739T>G p.M580R | Missense Mutation (SNP) | VAF 68/452 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A4A | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MUC5AC | c.14869C>A p.H4957N | Missense Mutation (SNP) | VAF 126/531 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MYH14 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYT1 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 80/362 reads (22%) | called by muse, mutect2, varscan2
- NAA16 | c.337A>C p.N113H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEA | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NEFM | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NEUROD2 | c.995T>A p.L332Q | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- NKX3-2 | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLGN4Y | c.812-2A>T p.X271_splice | Splice Site (SNP) | VAF 45/175 reads (26%) | called by muse, mutect2, varscan2
- NRXN3 | c.345C>A p.S115R | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NTRK3 | c.2476G>A p.A826T (on ENST00000360948 / NM_001012338.2; = p.A812T on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/346 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2
- OR10J3 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 80/385 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR14A16 | c.901T>A p.L301M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2
- OR2T4 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 70/654 reads (11%) | called by mutect2, varscan2
- OR4A5 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4C13 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OR4C5 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 55/348 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5W2 | c.834C>A p.Y278* | Nonsense Mutation (SNP) | VAF 29/177 reads (16%) | called by muse, mutect2, varscan2
- OR5W2 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR8D1 | c.291C>G p.C97W | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOP1 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- PAPPA2 | c.1538A>T p.Y513F | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PASK | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHA3 | c.1416C>A p.C472* | Nonsense Mutation (SNP) | VAF 120/604 reads (20%) | called by mutect2, varscan2
- PDE11A | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.046); called by muse, mutect2
- PFKP | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- PIEZO1 | c.3628G>T p.A1210S | Missense Mutation (SNP) | VAF 74/536 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PLCH1 | c.2140T>A p.C714S (on ENST00000340059 / NM_001130960.2; = p.C726S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PLXNA2 | c.5170G>T p.A1724S | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PLXNA4 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 75/354 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PM20D1 | c.1147_1179del p.D383_A393del | In Frame Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel
- PNLIP | c.574T>A p.L192M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPP6R1 | c.1605C>G p.D535E | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PREX2 | c.1105G>T p.G369* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- PRRT1 | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRT3 | c.2414G>T p.R805L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSKH2 | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 66/438 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PWWP3B | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RALYL | c.533del p.G178Dfs*14 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | called by pindel, varscan2
- RASA1 | c.2184+2T>C p.X728_splice | Splice Site (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
- RAX | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 78/481 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RGS1 | c.186A>T p.E62D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, varscan2
- RIN2 | c.1469C>T p.S490L (on ENST00000255006 / NM_001242581.1; = p.S441L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/469 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2
- ROBO3 | c.3100G>T p.G1034W | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- RPS4Y2 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2
- RYR3 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMD7 | c.702C>A p.N234K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SAR1B | c.387A>G p.I129M | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SCART1 | c.687C>A p.H229Q | Missense Mutation (SNP) | VAF 52/620 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SCN10A | c.4244G>T p.G1415V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A12 | c.2027G>T p.W676L (on ENST00000377369 / NM_001145195.2; = p.W639L on NM_152725.3) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SPTBN1 | c.6616C>G p.R2206G | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SUSD4 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- TGFB1I1 | c.1031del p.P344Rfs*69 (on ENST00000394863 / NM_001042454.3; = p.P327Rfs*69 on NM_015927.4) | Frame Shift Del (DEL) | VAF 112/564 reads (20%) | called by mutect2, pindel, varscan2
- TICRR | c.4933C>G p.Q1645E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TMC4 | c.973G>A p.E325K (on ENST00000617472 / NM_001145303.3; = p.E319K on NM_144686.4) | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.422); called by muse, mutect2
- TMEM132A | c.1598A>T p.E533V (on ENST00000453848 / NM_178031.3; = p.E534V on NM_017870.4) | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2
- TMEM245 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, varscan2
- TNNT1 | c.824del p.G275Afs*24 | Frame Shift Del (DEL) | VAF 107/425 reads (25%) | called by mutect2, pindel, varscan2
- TNRC18 | c.1049_1050del p.A350Gfs*16 | Frame Shift Del (DEL) | VAF 44/122 reads (36%) | called by pindel, varscan2
- TP53TG5 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- XCL2 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZFHX4 | c.5723C>G p.A1908G | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFPM2 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF12 | c.2033G>C p.S678T (on ENST00000405858 / NM_016265.4; = p.S640T on NM_006956.3) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF184 | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- ZNF264 | c.1747G>T p.V583F | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2
- ZNF267 | c.1690A>T p.I564F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- ZNF860 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF860 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); called by muse, varscan2
- ZNF860 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADGRB1 | c.1215G>T p.V405= | Silent (SNP) | VAF 34/166 reads (20%) | called by muse, mutect2, varscan2
- AFF2 | c.1863G>C p.V621= | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- AL035078.4 | c.33G>A p.A11= | Silent (SNP) | VAF 20/350 reads (6%) | catalogued as rs778711468; called by muse, mutect2
- APLNR | c.1062C>T p.P354= | Silent (SNP) | VAF 39/251 reads (16%) | catalogued as rs376524097; called by muse, mutect2, varscan2
- ARHGEF19 | c.1998C>T p.H666= | Silent (SNP) | VAF 32/338 reads (9%) | catalogued as rs770588521, COSV54615976, COSV99580085; called by muse, mutect2
- ASPG | c.996C>A p.A332= | Silent (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- BRAF | c.1755G>A p.E585= (on ENST00000288602 / NM_001374244.1; = p.E545= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as rs763895273; called by muse, mutect2, varscan2
- C1QC | c.120C>T p.G40= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs765845446; called by muse, mutect2
- C1orf167 | c.2805C>T p.T935= | Silent (SNP) | VAF 26/281 reads (9%) | called by muse, mutect2
- CACNA1G | c.5562G>T p.L1854= | Silent (SNP) | VAF 44/277 reads (16%) | catalogued as COSV100661076; called by muse, mutect2, varscan2
- CBLN1 | c.30G>T p.L10= | Silent (SNP) | VAF 12/80 reads (15%) | called by mutect2, varscan2
- CCN3 | c.669G>T p.G223= | Silent (SNP) | VAF 99/541 reads (18%) | catalogued as COSV52383998; called by muse, mutect2, varscan2
- CD96 | c.528C>A p.T176= | Silent (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- CDH16 | c.1248G>T p.L416= | Silent (SNP) | VAF 41/248 reads (17%) | catalogued as rs750627022; called by muse, mutect2, varscan2
- CHD7 | c.3834A>C p.P1278= | Silent (SNP) | VAF 61/297 reads (21%) | called by muse, mutect2, varscan2
- CNGB1 | c.472C>T p.L158= | Silent (SNP) | VAF 34/411 reads (8%) | called by muse, mutect2
- DACT1 | c.466C>A p.R156= | Silent (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- DDR2 | c.2376G>T p.L792= | Silent (SNP) | VAF 74/411 reads (18%) | called by muse, mutect2, varscan2
- DNAH17 | c.5868C>G p.R1956= | Silent (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- ERICH3 | c.2562G>T p.G854= | Silent (SNP) | VAF 24/107 reads (22%) | called by mutect2, varscan2
- FBN2 | c.3159C>A p.P1053= | Silent (SNP) | VAF 100/445 reads (22%) | catalogued as COSV99327108; called by muse, mutect2, varscan2
- FBN3 | c.5952C>T p.T1984= | Silent (SNP) | VAF 56/244 reads (23%) | called by muse, mutect2, varscan2
- GARS1 | c.199C>T p.L67= | Silent (SNP) | VAF 30/398 reads (8%) | catalogued as rs1472852130; called by muse, mutect2
- GFI1B | c.432C>G p.P144= | Silent (SNP) | VAF 36/279 reads (13%) | called by muse, mutect2, varscan2
- GNL3L | c.219C>T p.A73= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs145536873; called by muse, mutect2, varscan2
- GRM7 | c.954C>A p.S318= | Silent (SNP) | VAF 24/146 reads (16%) | called by muse, varscan2
- HTR1A | c.1092G>T p.V364= | Silent (SNP) | VAF 71/323 reads (22%) | called by muse, mutect2, varscan2
- IFIH1 | c.18C>T p.S6= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- IRF2BPL | c.1470C>T p.P490= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs1323039940; called by muse, mutect2, varscan2
- ITPKA | c.1317C>T p.N439= | Silent (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- JAG2 | c.3228C>T p.G1076= | Silent (SNP) | VAF 94/505 reads (19%) | catalogued as rs763305495; called by muse, mutect2, varscan2
- KCNG1 | c.600C>T p.A200= | Silent (SNP) | VAF 43/413 reads (10%) | catalogued as rs765498380; called by muse, mutect2, varscan2
- KCTD12 | c.219C>A p.A73= | Silent (SNP) | VAF 41/190 reads (22%) | catalogued as rs146434030; called by muse, mutect2, varscan2
- LMNB2 | c.408G>A p.K136= | Silent (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2
- MAP2 | c.2601G>T p.L867= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- MTARC1 | c.846C>T p.T282= | Silent (SNP) | VAF 53/286 reads (19%) | catalogued as rs147587306; called by muse, mutect2, varscan2
- NCAPG2 | c.1440G>T p.V480= | Silent (SNP) | VAF 61/300 reads (20%) | called by muse, mutect2, varscan2
- NOTCH3 | c.2019G>T p.V673= | Silent (SNP) | VAF 72/361 reads (20%) | called by muse, mutect2, varscan2
- NRXN3 | c.2406G>T p.V802= (on ENST00000335750 / NM_001330195.2; = p.V429= on NM_004796.6) | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- OGA | c.879G>T p.L293= | Silent (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- OR1J1 | c.894G>A p.K298= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV99403237; called by muse, mutect2, varscan2
- OR1L8 | c.475C>T p.L159= | Silent (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- OR2G3 | c.141C>A p.I47= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as COSV60681988, COSV60682501; called by muse, mutect2, varscan2
- OR4C13 | c.237G>T p.L79= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs150235959; called by muse, mutect2, varscan2
- OR51G1 | c.420T>A p.P140= | Silent (SNP) | VAF 25/272 reads (9%) | called by muse, mutect2
- OR5W2 | c.261C>A p.A87= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1788G>T p.S596= | Silent (SNP) | VAF 131/830 reads (16%) | catalogued as COSV50835152; called by muse, mutect2, varscan2
- PCDHB9 | c.1641G>T p.V547= | Silent (SNP) | VAF 201/835 reads (24%) | called by muse, mutect2, varscan2
- PDE11A | c.2530C>A p.R844= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs201342035, COSV53692996; called by muse, mutect2, varscan2
- PLAG1 | c.468G>A p.L156= | Silent (SNP) | VAF 43/832 reads (5%) | called by muse, mutect2
- PLK3 | c.660C>T p.I220= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- PMFBP1 | c.468G>A p.K156= | Silent (SNP) | VAF 44/352 reads (13%) | catalogued as rs540383418; called by muse, mutect2, varscan2
- POTEI | c.117C>A p.G39= | Silent (SNP) | VAF 72/493 reads (15%) | called by muse, mutect2, varscan2
- PRR23B | c.249A>G p.A83= | Silent (SNP) | VAF 65/223 reads (29%) | catalogued as rs931481926; called by muse, mutect2, varscan2
- PSKH2 | c.1005C>A p.A335= | Silent (SNP) | VAF 65/438 reads (15%) | called by muse, mutect2, varscan2
- PSMC3 | c.693G>T p.T231= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- RASSF2 | c.309T>G p.T103= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs748726236; called by muse, mutect2, varscan2
- RAX | c.396C>A p.P132= | Silent (SNP) | VAF 75/482 reads (16%) | called by muse, mutect2, varscan2
- RHBG | c.96C>A p.V32= | Silent (SNP) | VAF 61/320 reads (19%) | called by muse, mutect2, varscan2
- ROBO3 | c.2922G>T p.S974= | Silent (SNP) | VAF 49/262 reads (19%) | catalogued as COSV67300452; called by muse, mutect2, varscan2
- RPL13A | c.51C>T p.G17= | Silent (SNP) | VAF 101/391 reads (26%) | called by muse, mutect2, varscan2
- SATB2 | c.81C>A p.P27= | Silent (SNP) | VAF 36/396 reads (9%) | called by muse, mutect2
- SEL1L3 | c.738G>T p.V246= | Silent (SNP) | VAF 31/178 reads (17%) | called by muse, mutect2, varscan2
- SHPK | c.205C>T p.L69= | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as rs1449523762; called by muse, mutect2, varscan2
- SLC12A3 | c.2085G>T p.G695= | Silent (SNP) | VAF 48/480 reads (10%) | catalogued as COSV52635273; called by muse, mutect2
- SMPD4 | c.2370G>A p.L790= (on ENST00000409031 / NM_017951.4; = p.L761= on NM_017751.4) | Silent (SNP) | VAF 47/313 reads (15%) | called by muse, mutect2, varscan2
- SOD3 | c.222G>A p.A74= | Silent (SNP) | VAF 89/719 reads (12%) | catalogued as rs1455713623, COSV101181099; called by muse, mutect2, varscan2
- SYT13 | c.297C>T p.D99= | Silent (SNP) | VAF 66/446 reads (15%) | catalogued as rs776030930; called by muse, mutect2, varscan2
- TBX4 | c.861A>T p.T287= | Silent (SNP) | VAF 45/387 reads (12%) | called by muse, mutect2, varscan2
- TMEM177 | c.318C>T p.I106= | Silent (SNP) | VAF 43/228 reads (19%) | called by muse, mutect2, varscan2
- TMEM237 | c.951T>C p.F317= (on ENST00000409883 / NM_001044385.3; = p.F309= on NM_152388.4) | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- TNFRSF17 | c.396C>T p.I132= | Silent (SNP) | VAF 50/302 reads (17%) | called by muse, mutect2, varscan2
- VPS18 | c.1581C>A p.L527= | Silent (SNP) | VAF 85/341 reads (25%) | called by muse, mutect2, varscan2
- WDCP | c.1920C>G p.L640= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV54592245; called by muse, mutect2
- ZNF256 | c.603A>C p.A201= | Silent (SNP) | VAF 63/234 reads (27%) | called by muse, mutect2, varscan2
- ZNF469 | c.3390G>T p.P1130= (on ENST00000437464; = p.P1158= on NM_001367624.2) | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- ZNF532 | c.801C>T p.L267= | Silent (SNP) | VAF 18/321 reads (6%) | called by muse, mutect2
- ACAA2 | chr18:49814316 G>T | 5'Flank (SNP) | VAF 43/266 reads (16%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-3859G>C | Intron (SNP) | VAF 64/680 reads (9%) | called by muse, mutect2
- AMPH | c.1182+545G>T | Intron (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-67G>T | 5'UTR (SNP) | VAF 51/213 reads (24%) | catalogued as COSV56043757; called by muse, mutect2, varscan2
- BAIAP2 | chr17:81031071 C>T | 5'Flank (SNP) | VAF 35/503 reads (7%) | catalogued as rs1484773860; called by muse, mutect2
- CACNA1B | c.530+9479C>A | Intron (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
- CELF4 | c.1165+77C>A | Intron (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- CNTN1 | c.*31A>T | 3'UTR (SNP) | VAF 109/370 reads (29%) | called by muse, mutect2, varscan2
- DNM1P46 | n.521C>A | RNA (SNP) | VAF 88/483 reads (18%) | called by mutect2, varscan2
- ENPEP | c.1510-945C>A | Intron (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- FAM153A | c.-56-4515G>C | Intron (SNP) | VAF 8/158 reads (5%) | catalogued as rs760155815; called by muse, mutect2
- GVINP1 | n.4061C>T | RNA (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- H2BC18 | c.*1G>C | 3'UTR (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- H2BP2 | n.1061+561C>T | Intron (SNP) | VAF 13/173 reads (8%) | called by muse, mutect2, varscan2
- LHX8 | c.*29G>T | 3'UTR (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99633928; called by muse, mutect2
- MACF1 | c.15832-9997G>C | Intron (SNP) | VAF 17/181 reads (9%) | called by muse, mutect2
- NEURL3 | c.514+30A>T | Intron (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- NPSR1 | c.1026-227C>T | Intron (SNP) | VAF 45/231 reads (19%) | catalogued as rs1234557130; called by muse, mutect2, varscan2
- NSMAF | c.*9T>G | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, varscan2
- OR7E5P | n.185A>T | RNA (SNP) | VAF 66/346 reads (19%) | called by muse, mutect2, varscan2
- PRDM16 | c.*2G>T | 3'UTR (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99579263; called by muse, mutect2, varscan2
- PRKD3 | c.1778-815T>C | Intron (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- RNF220 | c.907-201G>C | Intron (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- SAMD11 | c.870-25C>A | Intron (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- SCN4B | c.*462C>A | 3'UTR (SNP) | VAF 43/328 reads (13%) | called by muse, mutect2, varscan2
- SEC61A2 | c.-102G>C | 5'UTR (SNP) | VAF 46/250 reads (18%) | catalogued as rs1369361426; called by muse, mutect2, varscan2
- SERPING1 | c.1029+225G>T | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1308C>T | RNA (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*870T>G | 3'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
